Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4146, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4146-01B (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Kidney, right, nephrectomy

Tumor histologic type/subtype: Renal cell carcinoma, clear cell subtype

Histologic grade (if applicable): Fuhrman grade 2 (of 4)

Tumor size (greatest dimension): 4.5 cm

Extent of tumor invasion:

Extra-capsular invasion: not identified

Renal vein: not involved

Ureter: not involved

Venous (large vessel) not involved

Lymphatic (small vessel): not involved

Surgical margins:

Perirenal adipose tissue: not involved

Renal vein: not involved

Renal artery: not involved

Ureter: not involved

Adrenal gland: not submitted

Lymph nodes: none submitted

Other significant findings: none

AJCC Stage: pT1b pNx pMx

This staging information is based on information available

[page 2 of 3]
at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:
with a renal mass.

Gross Description:
Specimen fixation: formalin

Type of specimen: nephrectomy, NOS

Side of specimen: right

Size and weight of specimen: 281.4 grams, 14.5 x 8.0 x 5.0 cm overall dimensions composed of a 13.3 x 6 x 3.5 cm kidney with a small amount of attached perinephric fat and a 3 cm length of ureter.

No adrenal gland is identified.

Orientation: The external surface is marked with blue ink.

Presence/absence of adrenal gland: absent

Tumor description/site: The tumor is located in the superior/medial pole of the kidney and is a solitary circumscribed, orange/red soft nodule.

Tumor size: 4.5 x 4.4 x 4.2 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: appears confined to the kidney

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve

Gerota's fascia: tumor grossly does not involve

Renal vein: tumor grossly does not involve

Ureter: tumor grossly does not involve

Other organs: tumor grossly does not involve

Surgical margins:

Perirenal adipose tissue: grossly negative

Renal vein: grossly negative

[page 3 of 3]
Renal artery: grossly negative
Ureter: grossly negative

Description of kidney away from tumor: Dark red/brown, homogeneous with an average cortical thickness of 0.6 cm. The pelvic urothelium is velvety, red/tan and of normal caliber. The ureter is patent.

Lymph nodes (hilar): No hilar lymph nodes are identified, but representative from the hilar fat is submitted for evaluation.

Other significant findings: none

Tissue submitted for special investigations: Tumor and normal are given to Tissue Procurement

Digital photograph taken: no

Block summary:

- A1 - ureter and vascular margins of resection, en face
- A2 - tumor expanding renal capsule
- A3 - tumor in relationship to posterior perinephric fat
- A4 - tumor in relationship to blue inked capsular margin, posterior
- A5 - tumor and normal renal parenchyma
- A6 - normal kidney away from tumor
- A7-A8 - representative sections from hilar adipose

Source: NCI Genomic Data Commons file 9db8268c-46a9-4d0b-89bc-a4b18e81996d (TCGA-B8-4146.D4A0B297-B80E-48B0-9FEF-1A1678AFF9BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).